CCDI case PBBTBL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Vagina.
https://portal.gdc.cancer.gov/cases/8258506d-94d7-4595-b95d-6bcbb8a89366

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 10.6 years (3,869 days).

Biospecimens (4 samples)
- Sample 0DGFTN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DGFVV, 0DGFW5 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGZ5R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
